Gene-level copy-number profile of tumor specimen TCGA-DY-A1DD-01A from TCGA case TCGA-DY-A1DD, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 77.1 years (28,159 days).
Specimen TCGA-DY-A1DD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.f3aaa596-93e0-4a4a-8f05-0d78185d5347.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DY-A1DD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0c0e2fec-ff9d-4502-a158-ca5798a1ef22

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 8,284; copy number 2: 41,603; copy number 3: 2,709; copy number 4: 4,884; copy number 5: 1,847; copy number 8: 327; copy number 10: 162.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DY-A1DD-01A-21D-A151-01): tumor purity 0.88, ploidy 2.2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:14,884,250–15,022,958, 4 genes (within-gene range 0–2): MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,336 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,789,179–19,895,973, 2 genes, copy number 5 (within-gene range 1–5): AL158077.2, AL158077.1.
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 5 (broad region; genes not listed).
- chr20:87,250–1,557,705, 47 genes, copy number 5: DEFB125, DEFB126, DEFB127, DEFB128, DEFB129, DEFB132, AL034548.1, C20orf96, ZCCHC3, AL034548.2, NRSN2-AS1, SOX12, NRSN2, TRIB3, RBCK1, TBC1D20, Y_RNA, CSNK2A1, TCF15, SRXN1, AL121758.1, SCRT2, SLC52A3, FAM110A, RPS10P5, ANGPT4, RSPO4, AL110114.1, PSMF1, ACTG1P3, TMEM74B, AL031665.1, C20orf202, RAD21L1, SNPH, SDCBP2, AL136531.2, AL136531.3, SDCBP2-AS1, AL136531.1, FKBP1A, MIR6869, NSFL1C, SIRPB2, AL049634.1, RNU6-917P, SIRPD.
- chr20:30,294,550–64,313,132, 896 genes, copy number 5–10 (within-gene range 2–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,274. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
